Somatic mutation profile of tumor specimen C3L-02352-01 (aliquot CPT0104430009) from CPTAC case C3L-02352, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.7 years (24,735 days).
Specimen C3L-02352-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51c4177c-0741-45fd-9709-08a656438051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02352-31 (Blood Derived Normal), aliquot CPT0105130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1e704e6-043f-41e3-a663-50bd9e6c3ad5

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Intron 6, Nonsense Mutation 5, Splice Site 3, 5'UTR 3, Frame Shift Del 3, RNA 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP5 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63701190; called by muse, mutect2, varscan2
- CNGA3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs770308610, CM101949, COSV55623584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC30 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs782788828; called by muse, mutect2
- GALNT3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 130/258 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV67061671; called by muse, mutect2, varscan2
- GDF10 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1555207526; called by muse, mutect2, varscan2
- IGSF1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs776789329, COSV63837383; called by muse, mutect2
- KIAA1328 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1568551978; called by muse, mutect2, varscan2
- KIF6 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749063566, COSV54666093; called by muse, mutect2, varscan2
- MTOR | c.7501A>T p.I2501F | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV63871874; called by muse, mutect2, varscan2
- MXRA5 | c.3536C>A p.T1179N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV54244237; called by muse, mutect2, varscan2
- NCLN | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs777878470; called by muse, mutect2, varscan2
- NLRP6 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV56458342; called by muse, mutect2, varscan2
- NTN3 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1450586781; called by muse, mutect2, varscan2
- PAPPA2 | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100867698; called by muse, varscan2
- PBRM1 | c.4222G>T p.E1408* (on ENST00000296302 / NM_001366071.2; = p.E1356* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 102/281 reads (36%) | catalogued as COSV56273837; called by muse, mutect2, varscan2
- RFX1 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 79/351 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.039); catalogued as rs753483809; called by muse, mutect2, varscan2
- SYNE1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 131/475 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs200346529, COSV55054396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WIPI1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs554506311, COSV100048664; called by muse, mutect2, varscan2
- AC008397.2 | c.1500C>A p.D500E | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANGPTL4 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP3D1 | c.2525A>T p.K842M | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CEP164 | c.21_25dup p.G9Afs*2 | Frame Shift Ins (INS) | VAF 47/221 reads (21%) | called by mutect2, pindel, varscan2
- DNAH8 | c.4024T>A p.F1342I | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNHD1 | c.13814del p.N4605Mfs*25 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- DPY19L3 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- FAM91A1 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- GABRD | c.848-1_866delinsA p.X283_splice | Splice Site (DEL) | VAF 59/152 reads (39%) | called by pindel, varscan2*
- HMGB2 | c.37A>G p.M13V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INSYN2B | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- JMJD1C | c.486C>A p.N162K | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- KIF27 | c.3481C>T p.Q1161* | Nonsense Mutation (SNP) | VAF 68/296 reads (23%) | called by muse, mutect2, varscan2
- KIF3B | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMNB2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRFN2 | c.1536G>T p.Q512H | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NAXD | c.841_858del p.L281_H286del | In Frame Del (DEL) | VAF 56/233 reads (24%) | called by mutect2, pindel, varscan2
- NOL10 | c.1406G>T p.W469L | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NTN3 | c.602del p.P201Qfs*15 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- NWD2 | c.4820G>T p.G1607V | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2
- OLFM3 | c.653-2A>C p.X218_splice (on ENST00000338858 / NM_001288821.1; = p.X198_splice on NM_058170.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- PCCA | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PLD2 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- POLR3A | c.2075-3_2077del p.X692_splice | Splice Site (DEL) | VAF 70/366 reads (19%) | called by mutect2, pindel, varscan2
- PPIP5K2 | c.3358G>T p.E1120* (on ENST00000358359 / NM_001276277.3; = p.E1099* on NM_015216.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- RAB29 | c.378+8G>A | Splice Region (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- RBBP4 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- RRM1 | c.81T>A p.Y27* | Nonsense Mutation (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- SLC2A10 | c.488del p.G163Dfs*82 | Frame Shift Del (DEL) | VAF 124/494 reads (25%) | called by mutect2, varscan2
- SLC2A10 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 126/487 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); called by mutect2, varscan2
- TMPRSS9 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TTN | c.12440C>A p.P4147H (on ENST00000591111; = p.P4101H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/495 reads (3%) | called by muse, mutect2
- VSTM2A | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2B3 | c.2280G>A p.R760= | Silent (SNP) | VAF 81/244 reads (33%) | called by muse, mutect2, varscan2
- CACNA1F | c.4182C>T p.P1394= | Silent (SNP) | VAF 68/252 reads (27%) | catalogued as rs373165717, COSV59904421; called by muse, mutect2, varscan2
- DBH | c.895C>T p.L299= | Silent (SNP) | VAF 48/171 reads (28%) | called by muse, mutect2, varscan2
- DCHS1 | c.5988T>C p.N1996= | Silent (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- DPYD | c.2259A>T p.A753= | Silent (SNP) | VAF 22/330 reads (7%) | called by muse, mutect2
- FITM2 | c.240C>T p.N80= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as rs559516581; called by muse, mutect2, varscan2
- IGHA1 | c.819C>T p.R273= | Silent (SNP) | VAF 85/579 reads (15%) | catalogued as rs778291607; called by muse, mutect2, varscan2
- MRC1 | c.2820G>A p.S940= | Silent (SNP) | VAF 116/422 reads (27%) | catalogued as rs782698035; called by muse, mutect2, varscan2
- MTA3 | c.1662G>A p.L554= (on ENST00000405094 / NM_001330442.2; = p.L497= on NM_001282755.1) | Silent (SNP) | VAF 68/275 reads (25%) | catalogued as rs957561306; called by muse, mutect2, varscan2
- MUC17 | c.7149C>T p.D2383= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs138267850, COSV100075844, COSV60305969; called by muse, mutect2, varscan2
- NOVA2 | c.642C>T p.Y214= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs1445620666; called by muse, mutect2, varscan2
- OR2T27 | c.249C>T p.V83= | Silent (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1507G>T | RNA (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-145C>A | 5'UTR (SNP) | VAF 41/125 reads (33%) | catalogued as rs936954862; called by muse, mutect2, varscan2
- C2orf81 | c.-34C>T | 5'UTR (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- INPP5K | c.*34G>A | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- NCR1 | c.70+25G>C | Intron (SNP) | VAF 72/283 reads (25%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44407G>A | Intron (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- TACC2 | c.5834+20217G>T | Intron (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- TEN1 | c.-3C>T | 5'UTR (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- TMEM254 | c.251+4059G>T | Intron (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- TMEM254 | c.251+4060T>G | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- USH1C | c.1285-7522C>T | Intron (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
